Surgical pathology report (de-identified scan), TCGA case TCGA-78-7160, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7160-01A (Primary Tumor).

[page 1 of 2]
HISTORY

(R) pneumonectomy for malignancy.

MACROSCOPIC

Four specimens received:

1: The specimen is labelled 'right lung' and consists of a right pneumonectomy measuring 215 mm superior to inferior, 180 mm anterior to posterior and 60 mm medial to lateral in the inflated state. On the pleural surface of the medial aspect of the lower lobe there is an area of puckering abutting the hilar resection margin measuring approximately 70 x 40 x 55 mm. On sectioning, a pale poorly-defined firm mass is present in the lower lobe extending from the bronchus and hilar resection margin and measuring 50 x 45 x 70 mm. The tumour is 4 mm to the closest bronchial resection margin and up to 2 mm from the interlobar fissure, 25 mm from the lateral pleural surface and appears to involve the pleura on the medial aspect of the lobe. No other lesions are noted in the upper or middle lobes, the lung parenchyma appearing normal. Please note the lung has been sampled for research. [Bronchial margin and pulmonary artery margin, 1A; hilar resection margin, 1B-C; bronchial resection margin, 1D; tumour and medial pleural surface, 1E; tumour and bronchus, 1F; tumour to interlobar fissure, 1G; tumour, 1H; tumour and lung parenchyma, 1I; normal lung tissue lower lobe, 1J; normal lung tissue middle lobe, 1K; normal lung tissue upper lobe, 1L; peribronchial lymph nodes, 1M-O].

2: The specimen is labelled 'hilar lymph node' and consists of a piece of dark brown tissue measuring 11 x 4 x 5 mm. [Wrapped, BIT, 2A].

3: The specimen is labelled 'subcarinal lymph node right' and consists of a piece of pale firm tissue covered in fat measuring 38 x 32 x 24 mm. On sectioning, there are five lymph nodes within the tissue, the largest measuring 26 x 12 x 10 mm. [Large lymph node, 3A-C; 1 lymph node bisected, 3D; 2 lymph nodes bisected, 3E].

4: The specimen is labelled 'upper medial sternal node (right)' and consists of a piece of fatty tissue containing a lymph node measuring 20 x 9 x 10 mm. [Bisected and BIT, 4A].

MICROSCOPIC

1: Sections show a moderately differentiated adenocarcinoma. In areas, there is production of abundant mucin by the tumour cells. A small micropapillary component is identified. Numerous psammoma bodies are identified within the tumour. The lesion is arising in the region of the hilum and is invading into soft tissue around bronchi and large pulmonary vessels. A separate deposit measuring 1.4 mm is identified in the random sections from the lower lobe and there is a deposit measuring 0.7 mm in diameter in the random sections from the middle lobe. Carcinoma is identified in the random sections from the upper lobe but this is in a lymphangitis carcinomatosa pattern. Pleural invasion is not identified. There is no blood vessel invasion but there is prominent lymphatic permeation is seen. No perineural permeation is identified. Lymphatic permeation by carcinoma is identified within the lamina propria of the bronchial resection margin. Tumour approaches the hilar resection margin. In most areas carcinoma is separated from hilar tissues that in visceral pleura but in some areas the lung has been transected. In one area in particular, tumour is approximately 0.5 mm from the diathermied margin. Peribronchial lymph node metastases are seen. All the lymph node Cross sections appear to contain at least some tumour and there is lymphatic permeation within the surrounding soft tissue. The lung shows evidence of mild centriacinar emphysema that is best seen within the upper lobe.

2-4: Sections show focal to extensive involvement of the lymph nodes by metastatic adenocarcinoma.

SUMMARY

1-4: Right lung and hilar, subcarinal and upper 'medial sternal' lymph nodes:

A: Moderately differentiated adenocarcinoma; 70 mm in maximal dimension.

B: Prominent lymphatic permeation but no blood vessel or perineural invasion present.

C: Lymphatic permeation at the bronchial margin; tumour very close to hilar soft tissue margin; no definite pleural invasion identified.

D: Peribronchial, hilar, subcarinal and upper 'medial sternal' lymph node metastases.

E: T4N2M1

F: Non-neoplastic lung: Lymphangitis carcinomatosa; mild emphysema.

[page 2 of 2]
T-28000 M-81403 P1-03000

Source: NCI Genomic Data Commons file 0a4ac48e-81d9-43c0-9039-14ab61c4ac0a (TCGA-78-7160.A654D277-9F15-4E8B-B1A5-93FD802C5D36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).